Somatic mutation profile of tumor specimen MMRF_1360_1_BM_CD138pos (aliquot MMRF_1360_1_BM_CD138pos_T1_KAS5U_L00688) from MMRF case MMRF_1360, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.9 years (23,709 days).
Specimen MMRF_1360_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5fd0bc4-f09b-44c3-94fa-34d0618b51b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1360_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1360_1_PB_Whole_C2_KAS5U_L00696; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93845688-9f5c-4aa9-a17b-437fbb8e1011

The open-access MAF lists 97 somatic variants for this specimen: 30 protein-altering or splice-affecting, 14 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 26, Missense Mutation 25, Silent 14, Intron 12, RNA 5, 5'UTR 5, 3'Flank 4, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC16 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs142528073; called by muse, mutect2, varscan2
- CSNK1D | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as rs373816900; called by muse, varscan2
- EIF2AK3 | c.158C>G p.P53R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.159); catalogued as rs1361346758; called by muse, mutect2, varscan2
- GRM3 | c.468+1del | Frame Shift Del (DEL) | VAF 49/132 reads (37%) | catalogued as COSV100862529; called by mutect2, pindel, varscan2
- HRH4 | c.407T>C p.M136T | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1365663685; called by muse, mutect2, varscan2
- HTR2C | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.369); catalogued as rs868980082, COSV52202281; called by muse, mutect2, varscan2
- IGHV3-33 | c.284A>G p.K95R | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.168); catalogued as rs1555493561; called by muse, mutect2, varscan2
- IGLV3-1 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs371556422; called by muse, varscan2
- IGLV3-1 | c.238T>A p.F80I | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs561290535; called by muse, varscan2
- IGLV3-1 | c.314A>C p.Y105S | Missense Mutation (SNP) | VAF 76/126 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs185803370; called by muse, varscan2
- LARP1 | c.2680C>T p.R894C (on ENST00000518297 / NM_033551.3; = p.R817C on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60427689; called by muse, mutect2, varscan2
- LRIG3 | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT tolerated (0.48); PolyPhen benign (0.057); catalogued as rs140980524; called by muse, mutect2, varscan2
- NPAT | c.4139G>A p.R1380Q | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs372933437; called by muse, mutect2, varscan2
- OR51F1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs536873822, COSV58580427; called by muse, mutect2, varscan2
- PDE11A | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs77789692; called by muse, mutect2, varscan2
- TGFB1 | c.86G>C p.G29A | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.024); catalogued as rs199758510, CM090931, CM090932; called by muse, mutect2, varscan2
- TRPM6 | c.1763A>G p.K588R | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs1022275975; called by muse, mutect2, varscan2
- CLASP2 | c.581T>G p.I194S | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, varscan2
- CNTN2 | c.248A>G p.E83G | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYLC1 | c.557A>T p.Q186L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DDX46 | c.3048G>A p.L1016= | Splice Region (SNP) | VAF 41/120 reads (34%) | called by muse, mutect2, varscan2
- FBXW7 | c.1657dup p.H553Pfs*8 (on ENST00000281708 / NM_001349798.2; = p.H473Pfs*8 on NM_018315.5) | Frame Shift Ins (INS) | VAF 20/37 reads (54%) | called by mutect2, pindel, varscan2
- HBA1 | c.88del p.L30Wfs*20 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- IGSF21 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- NSUN5 | c.931T>A p.S311T | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PCDH15 | c.4550G>A p.S1517N (on ENST00000644397 / NM_001354429.2; = p.V1478I on NM_001142770.3) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RRM1 | c.1615G>T p.A539S | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- SNTG2 | c.890T>A p.V297D | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- XDH | c.3374C>G p.T1125R | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF497 | c.645G>T p.E215D | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ACTL7B | c.738C>T p.D246= | Silent (SNP) | VAF 30/155 reads (19%) | catalogued as COSV65928268, COSV65928383; called by muse, mutect2, varscan2
- BCL11B | c.1443C>G p.A481= (on ENST00000357195 / NM_001282237.2; = p.A410= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV61734471; called by muse, varscan2
- DENND1A | c.66C>T p.P22= | Silent (SNP) | VAF 108/249 reads (43%) | catalogued as COSV65332753; called by muse, mutect2, varscan2
- EIF2AK3 | c.159C>T p.P53= | Silent (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- ENO4 | c.1272G>A p.A424= (on ENST00000622726; = p.A421= on NM_001242699.2) | Silent (SNP) | VAF 42/78 reads (54%) | catalogued as rs563640397; called by muse, mutect2, varscan2
- IGLV3-1 | c.117C>T p.I39= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as rs558278447; called by muse, varscan2
- IGLV3-1 | c.129A>G p.G43= | Silent (SNP) | VAF 71/107 reads (66%) | catalogued as rs376383840; called by muse, varscan2
- IGLV3-1 | c.273G>A p.L91= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as rs546005036; called by muse, varscan2
- JADE2 | c.2289A>C p.V763= | Silent (SNP) | VAF 44/150 reads (29%) | called by muse, varscan2
- JUND | c.474C>T p.A158= | Silent (SNP) | VAF 9/12 reads (75%) | called by muse, mutect2, varscan2
- MFSD14B | c.1353A>G p.E451= | Silent (SNP) | VAF 45/191 reads (24%) | called by muse, mutect2, varscan2
- OR4S2 | c.741C>T p.I247= | Silent (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- RMI1 | c.1867T>C p.L623= | Silent (SNP) | VAF 25/44 reads (57%) | called by muse, mutect2, varscan2
- UBASH3A | c.996G>A p.P332= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as rs138698980; called by muse, mutect2, varscan2
- AC009237.3 | n.674G>A | RNA (SNP) | VAF 32/75 reads (43%) | catalogued as rs761748702; called by muse, mutect2, varscan2
- AL355916.3 | c.420-3701G>T | Intron (SNP) | VAF 38/78 reads (49%) | called by muse, mutect2, varscan2
- AL359195.2 | n.2887_2922del | RNA (DEL) | VAF 11/100 reads (11%) | called by mutect2, pindel
- APPBP2 | c.-20C>T | 5'UTR (SNP) | VAF 16/37 reads (43%) | catalogued as COSV50025972; called by muse, mutect2, varscan2
- ARAF | c.1551+34C>A | Intron (SNP) | VAF 48/103 reads (47%) | called by muse, mutect2, varscan2
- ATRX | c.5566+102T>A | Intron (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- BACE2 | c.312+10891G>A | Intron (SNP) | VAF 27/30 reads (90%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021465 C>A | 5'Flank (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1725C>T | RNA (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- C15orf54 | n.2789G>A | RNA (SNP) | VAF 43/61 reads (70%) | called by muse, mutect2, varscan2
- C5orf52 | c.*27C>T | 3'UTR (SNP) | VAF 67/101 reads (66%) | called by muse, mutect2, varscan2
- CTBP2 | c.*2950dup | 3'UTR (INS) | VAF 41/85 reads (48%) | catalogued as rs1203692881; called by mutect2, pindel, varscan2
- CYP4B1 | c.*422A>T | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- EXT1 | c.*263A>T | 3'UTR (SNP) | VAF 20/33 reads (61%) | called by muse, mutect2, varscan2
- FGF11 | c.*524C>G | 3'UTR (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- FRMD8 | c.*1658G>T | 3'UTR (SNP) | VAF 12/28 reads (43%) | called by muse, varscan2
- GDI1 | c.991+85C>T | Intron (SNP) | VAF 5/41 reads (12%) | catalogued as rs1557198986; called by muse, mutect2
- GSG1 | c.*544T>G | 3'UTR (SNP) | VAF 44/95 reads (46%) | called by muse, mutect2, varscan2
- GSTA4 | c.-18-58T>C | Intron (SNP) | VAF 43/112 reads (38%) | catalogued as COSV63373459; called by muse, mutect2, varscan2
- IL10RA | c.*891G>C | 3'UTR (SNP) | VAF 38/136 reads (28%) | catalogued as rs1168905429; called by muse, mutect2, varscan2
- INHBA | c.*3988T>G | 3'UTR (SNP) | VAF 27/43 reads (63%) | called by muse, mutect2, varscan2
- KAT6A | c.2436+337A>C | Intron (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- LDHA | c.-173G>A | 5'UTR (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- LEPROTL1 | c.*792A>G | 3'UTR (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- LRRC3 | c.*426A>C | 3'UTR (SNP) | VAF 42/45 reads (93%) | called by muse, mutect2, varscan2
- LTB | c.162+137C>T | Intron (SNP) | VAF 20/41 reads (49%) | catalogued as rs186447095, COSV53001762; called by muse, mutect2, varscan2
- MDGA1 | c.*4741C>T | 3'UTR (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
- MKRN2 | chr3:12584462 del C | 3'Flank (DEL) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- MRPL2 | c.-21A>G | 5'UTR (SNP) | VAF 14/44 reads (32%) | catalogued as rs372010766; called by muse, mutect2, varscan2
- OR52A4P | chr11:5120791 del A | 3'Flank (DEL) | VAF 60/85 reads (71%) | catalogued as rs769032953; called by mutect2, varscan2
- PDE3A | c.*2844T>G | 3'UTR (SNP) | VAF 26/64 reads (41%) | catalogued as rs567718198; called by muse, mutect2, varscan2
- PPIL2 | c.33-505C>A | Intron (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- PRR5 | c.*126G>A | 3'UTR (SNP) | VAF 32/70 reads (46%) | catalogued as rs942632491; called by muse, mutect2, varscan2
- PRTG | c.*2776del | 3'UTR (DEL) | VAF 10/56 reads (18%) | catalogued as rs986416810; called by pindel, varscan2
- RNF212 | c.*13T>G | 3'UTR (SNP) | VAF 43/105 reads (41%) | called by muse, mutect2, varscan2
- RPL13 | c.247-75C>T | Intron (SNP) | VAF 50/91 reads (55%) | called by muse, mutect2, varscan2
- SERF2 | c.117-204C>G | Intron (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- SFT2D1 | c.-22G>A | 5'UTR (SNP) | VAF 40/99 reads (40%) | called by muse, mutect2, varscan2
- SLC25A53 | c.*2546T>G | 3'UTR (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- SLCO4C1 | c.*1977C>T | 3'UTR (SNP) | VAF 61/195 reads (31%) | called by muse, mutect2, varscan2
- SLFN12L | c.*466G>A | 3'UTR (SNP) | VAF 21/51 reads (41%) | catalogued as rs1470217148; called by muse, mutect2, varscan2
- SNORD115-37 | n.29C>A | RNA (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
- SPRY3 | c.*3016G>T | 3'UTR (SNP) | VAF 51/126 reads (40%) | called by muse, mutect2, varscan2
- STAP2 | c.*58C>G | 3'UTR (SNP) | VAF 33/113 reads (29%) | catalogued as COSV99697009, COSV99697110; called by muse, mutect2, varscan2
- TBX19 | c.*723C>T | 3'UTR (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- TCP10L3 | n.2618+263A>G | Intron (SNP) | VAF 5/19 reads (26%) | catalogued as rs3010589; called by muse, varscan2
- TP53I11 | c.*385del | 3'UTR (DEL) | VAF 28/107 reads (26%) | called by mutect2, pindel, varscan2
- TRIM59 | chr3:160433006 G>A | 3'Flank (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- TSPAN8 | c.*151T>C | 3'UTR (SNP) | VAF 35/64 reads (55%) | called by muse, mutect2, varscan2
- ZBTB38 | chr3:141446263 A>G | 3'Flank (SNP) | VAF 30/114 reads (26%) | called by muse, mutect2, varscan2
- ZMAT4 | c.*518G>A | 3'UTR (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- ZNF12 | c.-131C>G | 5'UTR (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- ZNF275 | c.*975C>T | 3'UTR (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
